Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LK, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LK-01A (Primary Tumor).

Procedure: Right adrenalectomy

Gross Description: Tumor is 244g; measuring 8.2 x 7.5 x 6.5cm.

Diagnosis: Adrenal cortical carcinoma with oncocytic features. Weiss score = 5.

ICD-O-3

Carcinoma, adrenal cortical
w/oncocytic features

8370/3

Site: B Adrenal Gland cortex
C74.0

9/20/13

ICD-O Discrepancy		
Path Discrepancy		

Source: NCI Genomic Data Commons file 98c67db9-b66d-481a-973a-a91eb5374862 (TCGA-OR-A5LK.4917D13C-6355-4E4B-8189-FE4443313F53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).